CCDI case PBBVGC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/1ec2de37-0a4c-45e8-9cca-c0491dbc9625

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.9 years (5,813 days).

Biospecimens (3 samples)
- Sample 0DI5EG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI5EW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI5FM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
